Somatic mutation profile of tumor specimen TCGA-BQ-7045-01A (aliquot TCGA-BQ-7045-01A-31D-1961-08) from TCGA case TCGA-BQ-7045, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 78.6 years (28,709 days).
Specimen TCGA-BQ-7045-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 484dae8d-7f57-4b54-be8c-4cacb5ea8883.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BQ-7045-11A (Solid Tissue Normal), aliquot TCGA-BQ-7045-11A-01D-1961-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a79fc96d-a8bf-430a-b903-e3354c4b672f

The open-access MAF lists 83 somatic variants for this specimen: 59 protein-altering or splice-affecting, 19 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 19, Frame Shift Del 8, Frame Shift Ins 4, Splice Site 2, RNA 2, Intron 2, 3'UTR 1, Nonsense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADD2 | c.1825G>T p.A609S | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV100035202; called by muse, varscan2
- ALPK2 | c.5389T>C p.F1797L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.843); catalogued as COSV64489814; called by muse, mutect2, varscan2
- ATP2C1 | c.1249A>G p.R417G | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV60752088; called by muse, mutect2, varscan2
- AZI2 | c.43del p.E15Kfs*9 | Frame Shift Del (DEL) | VAF 42/123 reads (34%) | catalogued as COSV99843366; called by mutect2, pindel, varscan2
- CHCHD3 | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 32/62 reads (52%) | SIFT tolerated (0.08); PolyPhen benign (0.21); catalogued as COSV52769080; called by muse, mutect2, varscan2
- CLUAP1 | c.24T>C p.N8= | Splice Region (SNP) | VAF 20/95 reads (21%) | catalogued as rs1437871425, COSV58892378; called by muse, mutect2, varscan2
- CRTAP | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs757163727, COSV58012817; called by muse, mutect2
- DYNC1H1 | c.4054G>A p.V1352I | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (0.26); PolyPhen benign (0.173); catalogued as rs750180922, COSV64133949; called by muse, mutect2, varscan2
- DZIP1L | c.1031T>C p.L344P | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1184320485, COSV59518992; called by muse, mutect2, varscan2
- EIF4G1 | c.2453T>C p.M818T (on ENST00000346169 / NM_198241.3; = p.M623T on NM_004953.5) | Missense Mutation (SNP) | VAF 29/110 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as COSV59988679; called by muse, mutect2, varscan2
- ELAC1 | c.797G>C p.C266S | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV53996122; called by muse, mutect2, varscan2
- EVPL | c.4727G>A p.R1576Q | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.37); PolyPhen benign (0.035); catalogued as rs959240068, COSV56906718; called by muse, mutect2
- FERMT2 | c.167A>T p.K56I | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.248); catalogued as COSV58404902; called by muse, mutect2, varscan2
- GDF5 | c.191G>A p.S64N | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV65499059; called by muse, mutect2, varscan2
- GOLGA2 | c.553C>T p.Q185* | Nonsense Mutation (SNP) | VAF 35/98 reads (36%) | catalogued as COSV70167988; called by muse, mutect2, varscan2
- GPC6 | c.653C>G p.A218G | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV65495047; called by muse, mutect2, varscan2
- GPR18 | c.248C>T p.A83V | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV61620903; called by muse, mutect2, varscan2
- HTR2B | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.204); catalogued as COSV51448864; called by muse, mutect2, varscan2
- JAK3 | c.1921A>G p.K641E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV71685375; called by muse, varscan2
- KCNV1 | c.208G>T p.V70L | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.71); PolyPhen benign (0.118); catalogued as COSV52089384, COSV99818988; called by muse, mutect2, varscan2
- KIAA1522 | c.1838C>A p.P613Q (on ENST00000373480 / NM_001198972.2; = p.P672Q on NM_020888.3) | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV53862112; called by muse, mutect2, varscan2
- KRTAP13-1 | c.216G>T p.E72D | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as rs1334058569, COSV62662620; called by muse, mutect2, varscan2
- LAP3 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56898130; called by muse, mutect2, varscan2
- LRIG3 | c.563A>T p.D188V | Missense Mutation (SNP) | VAF 73/226 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV57860494; called by muse, mutect2, varscan2
- NDUFS6 | c.61C>A p.L21M | Missense Mutation (SNP) | VAF 19/38 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.161); catalogued as COSV56875690; called by muse, mutect2, varscan2
- NUB1 | c.1084C>A p.L362M | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63425710; called by muse, mutect2, varscan2
- OR4C15 | c.573G>C p.R191S (on ENST00000314644; = p.R137S on NM_001001920.2) | Missense Mutation (SNP) | VAF 44/150 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.005); catalogued as COSV58950880; called by muse, mutect2, varscan2
- PLIN4 | c.1462G>A p.V488M (on ENST00000301286; = p.V503M on NM_001367868.2) | Missense Mutation (SNP) | VAF 55/189 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as rs1256532772, COSV56685874; called by muse, mutect2, varscan2
- PPM1F | c.581T>C p.F194S | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54282519; called by muse, mutect2, varscan2
- PRKG2 | c.979G>T p.A327S | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV52318510; called by muse, mutect2, varscan2
- PTH1R | c.425-1G>T p.X142_splice | Splice Site (SNP) | VAF 33/166 reads (20%) | catalogued as COSV57314404; called by muse, mutect2, varscan2
- RAP2A | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV55354167; called by muse, mutect2, varscan2
- RPL10 | c.166G>A p.E56K | Missense Mutation (SNP) | VAF 48/81 reads (59%) | SIFT deleterious (0.01); PolyPhen benign (0.134); catalogued as COSV50009975, COSV99185975; called by muse, mutect2, varscan2
- SFI1 | c.223C>T p.H75Y | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as COSV66289502; called by muse, mutect2, varscan2
- SLC5A9 | c.1714C>T p.L572F | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.058); catalogued as COSV52581764; called by muse, mutect2
- SYNM | c.1709A>T p.K570M | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV60366894; called by muse, mutect2, varscan2
- THBS2 | c.3254C>A p.T1085K | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV64676880, COSV64682243; called by muse, mutect2, varscan2
- TIAF1 | c.264G>C p.R88S | Missense Mutation (SNP) | VAF 114/227 reads (50%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.123); catalogued as COSV62861972; called by muse, mutect2, varscan2
- TNRC6B | c.3070A>G p.T1024A (on ENST00000454349 / NM_001162501.2; = p.T971A on NM_015088.3) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs761994358, COSV57287510; called by muse, mutect2
- TRPV6 | c.2017G>T p.V673L | Missense Mutation (SNP) | VAF 22/124 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV100844172, COSV63890236; called by muse, mutect2, varscan2
- TSPOAP1 | c.4327C>A p.L1443M | Missense Mutation (SNP) | VAF 35/140 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV52103033; called by muse, mutect2, varscan2
- USH2A | c.3365C>T p.S1122F | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV56322278; called by muse, mutect2, varscan2
- USP19 | c.2999A>T p.E1000V | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV60044752; called by muse, mutect2, varscan2
- USP19 | c.2998G>A p.E1000K | Missense Mutation (SNP) | VAF 46/100 reads (46%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.687); catalogued as COSV60044756; called by muse, mutect2, varscan2
- ZNF626 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.404); catalogued as COSV74128847; called by muse, mutect2, varscan2
- ZNF763 | c.1142T>C p.F381S (on ENST00000358987 / NM_001367172.2; = p.F384S on NM_001012753.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/133 reads (38%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.481); catalogued as COSV59686995; called by muse, mutect2, varscan2
- ZSWIM4 | c.710A>G p.N237S | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.022); catalogued as COSV54318904; called by muse, mutect2, varscan2
- CISH | c.261del p.T88Rfs*18 (on ENST00000348721 / NM_145071.4; = p.T105Rfs*18 on NM_013324.6) | Frame Shift Del (DEL) | VAF 8/66 reads (12%) | called by mutect2, pindel, varscan2
- CRACD | c.2413del p.Y805Tfs*24 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | called by mutect2, pindel, varscan2
- DNAJC28 | c.651dup p.D218* | Frame Shift Ins (INS) | VAF 42/193 reads (22%) | called by mutect2, pindel, varscan2
- ENPP1 | c.720del p.K240Nfs*9 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | called by mutect2, pindel, varscan2
- GFRAL | c.725del p.S242* | Frame Shift Del (DEL) | VAF 39/128 reads (30%) | called by mutect2, pindel, varscan2
- HAPLN3 | c.506del p.P169Lfs*109 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- KDR | c.657dup p.G220Rfs*3 | Frame Shift Ins (INS) | VAF 21/86 reads (24%) | called by mutect2, pindel, varscan2
- MITF | c.594dup p.E199* (on ENST00000448226 / NM_006722.3; = p.E93* on NM_000248.4) | Frame Shift Ins (INS) | VAF 31/79 reads (39%) | called by mutect2, pindel, varscan2
- MRPL9 | c.160_173del p.V54Lfs*23 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel
- PLEKHB2 | c.605_607delinsGG p.A202Gfs*14 (on ENST00000409279; = p.A201Gfs*14 on NM_017958.2 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 64/272 reads (24%) | called by pindel, varscan2*
- PROX1 | c.560_561dup p.E188Mfs*12 | Frame Shift Ins (INS) | VAF 18/69 reads (26%) | called by mutect2, pindel, varscan2
- RASA2 | c.1934-11_1934-2del p.X645_splice | Splice Site (DEL) | VAF 25/37 reads (68%) | called by mutect2, pindel, varscan2
- ABCA4 | c.1884T>A p.A628= | Silent (SNP) | VAF 16/53 reads (30%) | catalogued as COSV64670604; called by muse, mutect2, varscan2
- ADGRA1 | c.1368C>T p.P456= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV63416363; called by muse, mutect2, varscan2
- AFDN | c.591A>C p.R197= | Silent (SNP) | VAF 80/254 reads (31%) | catalogued as COSV100652767; called by mutect2, varscan2
- AGFG2 | c.1155C>T p.P385= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as COSV53543830; called by muse, mutect2
- ANKRD12 | c.4026T>C p.T1342= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as COSV50818993; called by muse, mutect2, varscan2
- ASTN2 | c.3708C>A p.V1236= (on ENST00000313400 / NM_001365069.1; = p.V1185= on NM_014010.5) | Silent (SNP) | VAF 45/120 reads (38%) | catalogued as COSV55997541; called by muse, mutect2, varscan2
- ASXL3 | c.765A>G p.G255= | Silent (SNP) | VAF 13/51 reads (25%) | catalogued as COSV52455994; called by muse, mutect2, varscan2
- CLEC14A | c.912G>A p.R304= | Silent (SNP) | VAF 44/133 reads (33%) | catalogued as COSV60561524; called by muse, mutect2, varscan2
- CTH | c.618T>C p.S206= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV61007248; called by muse, mutect2, varscan2
- KCNH6 | c.2845C>T p.L949= | Silent (SNP) | VAF 30/147 reads (20%) | catalogued as rs951899355, COSV59000340, COSV59000795, COSV59004189; called by muse, mutect2, varscan2
- NDUFV3 | c.90T>C p.S30= | Silent (SNP) | VAF 24/83 reads (29%) | catalogued as COSV61086894; called by muse, mutect2, varscan2
- OR4K2 | c.831C>A p.I277= | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as COSV53847929; called by muse, mutect2, varscan2
- OSTC | c.27C>T p.F9= | Silent (SNP) | VAF 37/109 reads (34%) | catalogued as COSV64232066, COSV64232567; called by muse, mutect2, varscan2
- PCLO | c.13479T>C p.P4493= | Silent (SNP) | VAF 53/98 reads (54%) | catalogued as COSV61612860; called by muse, mutect2, varscan2
- SALL4 | c.2556C>T p.S852= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as COSV53849543; called by muse, mutect2, varscan2
- SNX6 | c.729T>A p.S243= (on ENST00000652385; = p.S115= on NM_021249.5) | Silent (SNP) | VAF 14/52 reads (27%) | catalogued as COSV61917488; called by muse, mutect2, varscan2
- TMEM101 | c.546G>A p.L182= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV52812741; called by muse, mutect2, varscan2
- TMEM156 | c.684C>A p.I228= | Silent (SNP) | VAF 27/113 reads (24%) | catalogued as COSV60743859; called by muse, mutect2, varscan2
- UBAC1 | c.342A>G p.Q114= | Silent (SNP) | VAF 13/34 reads (38%) | catalogued as COSV65613609; called by muse, mutect2, varscan2
- C2CD3 | c.5882-323del | Intron (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel, varscan2
- C6orf223 | n.696C>T | RNA (SNP) | VAF 34/81 reads (42%) | catalogued as COSV60735106; called by muse, mutect2, varscan2
- CNOT3 | c.2037+306A>C | Intron (SNP) | VAF 16/45 reads (36%) | catalogued as COSV99651654; called by muse, mutect2, varscan2
- LINC01600 | n.1054G>T | RNA (SNP) | VAF 24/65 reads (37%) | called by muse, mutect2, varscan2
- MFSD4B | c.*712A>T | 3'UTR (SNP) | VAF 58/198 reads (29%) | catalogued as COSV64348493; called by muse, mutect2, varscan2
